Somatic mutation profile of tumor specimen MMRF_1082_1_BM_CD138pos (aliquot MMRF_1082_1_BM_CD138pos_T2_TSE61_K02709) from MMRF case MMRF_1082, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.5 years (17,339 days).
Specimen MMRF_1082_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 487fcec9-e337-4a32-ac7e-3994fb33dbe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1082_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1082_1_PB_Whole_C1_TSE61_K02716; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/551b73fa-2bd7-4136-a176-7d5693822ac4

The open-access MAF lists 82 somatic variants for this specimen: 39 protein-altering or splice-affecting, 11 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 21, Silent 11, Nonsense Mutation 5, Frame Shift Del 3, RNA 3, Frame Shift Ins 2, 3'Flank 2, Intron 2, 5'UTR 2, IGR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 67/128 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY1 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs777652902, COSV99811214; called by muse, mutect2, varscan2
- BICDL2 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs923791212; called by muse, mutect2, varscan2
- C11orf87 | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.561); catalogued as rs756061851; called by muse, mutect2, varscan2
- DMBT1 | c.5350G>A p.V1784I (on ENST00000338354 / NM_001377530.1; = p.V1027I on NM_004406.3) | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.924); catalogued as rs747389264; called by muse, mutect2, varscan2
- FAM169A | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100998325; called by muse, mutect2, varscan2
- FKBP6 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as rs781881868, COSV99333678; called by muse, mutect2, varscan2
- HGF | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55946840; called by muse, mutect2, varscan2
- HOXB4 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751342746; called by muse, mutect2, varscan2
- IL22 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs1168981151; called by muse, mutect2, varscan2
- ITGAX | c.3086G>A p.R1029Q | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as rs777767407, COSV51652001, COSV99192076; called by muse, mutect2, varscan2
- PCDHA2 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 75/140 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV65364430; called by muse, mutect2, varscan2
- RNF4 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs770967471; called by muse, mutect2, varscan2
- SLC49A3 | c.1469C>T p.P490L (on ENST00000404286 / NM_001294341.2; = p.P489L on NM_032219.4) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs755096552, COSV59141841; called by muse, mutect2
- SPOPL | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54513546; called by muse, mutect2, varscan2
- TENT5C | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 77/78 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs780049033, COSV65616767; called by muse, mutect2, varscan2
- ZNF99 | c.2283C>A p.C761* | Nonsense Mutation (SNP) | VAF 55/364 reads (15%) | catalogued as COSV68056423; called by muse, mutect2, varscan2
- ABCC1 | c.4556G>A p.G1519D | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRE1 | c.288del p.C97Afs*13 | Frame Shift Del (DEL) | VAF 51/88 reads (58%) | called by mutect2, pindel*
- ADRA1D | c.1510del p.R504Gfs*41 | Frame Shift Del (DEL) | VAF 30/64 reads (47%) | called by mutect2, pindel, varscan2
- CDK13 | c.3307dup p.T1103Nfs*4 | Frame Shift Ins (INS) | VAF 51/111 reads (46%) | called by mutect2, pindel, varscan2
- COL6A3 | c.2052_2053del p.S684Rfs*57 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- EVC2 | c.2829G>T p.K943N | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- GPR45 | c.1070T>A p.I357N | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GRHL1 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- HIC2 | c.138T>A p.C46* | Nonsense Mutation (SNP) | VAF 39/84 reads (46%) | called by muse, mutect2, varscan2
- IL15 | c.66dup p.S23Qfs*6 | Frame Shift Ins (INS) | VAF 46/82 reads (56%) | called by mutect2, varscan2
- KLHL42 | c.1324T>G p.L442V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- MCCC1 | c.1372T>A p.Y458N | Missense Mutation (SNP) | VAF 67/96 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MUC16 | c.15730C>T p.P5244S | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO10 | c.4454C>T p.A1485V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP98 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPP4R3B | c.32A>C p.Y11S | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- SHKBP1 | c.418C>G p.R140G | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- SMU1 | c.1310C>A p.S437Y | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TMEM131L | c.1966C>T p.Q656* | Nonsense Mutation (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- TMEM177 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- TRIP12 | c.5738T>G p.L1913* | Nonsense Mutation (SNP) | VAF 55/120 reads (46%) | called by muse, mutect2, varscan2
- ZFP64 | c.1499T>C p.I500T | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- ADAM29 | c.93G>C p.P31= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as COSV100822012; called by muse, mutect2, varscan2
- ATAD2B | c.2433A>C p.T811= | Silent (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- ATP8B4 | c.3426C>T p.I1142= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as COSV52713148; called by muse, mutect2
- FAM47A | c.276C>T p.S92= | Silent (SNP) | VAF 75/75 reads (100%) | catalogued as rs1160295204, COSV60498356; called by muse, mutect2, varscan2
- FCHSD1 | c.1272C>T p.L424= | Silent (SNP) | VAF 49/88 reads (56%) | called by muse, mutect2, varscan2
- FLRT2 | c.1624C>T p.L542= | Silent (SNP) | VAF 46/90 reads (51%) | catalogued as COSV100421067, COSV58141203; called by muse, mutect2, varscan2
- IL9 | c.33G>A p.L11= | Silent (SNP) | VAF 49/129 reads (38%) | catalogued as rs1293016568; called by muse, mutect2, varscan2
- KCNF1 | c.681G>A p.T227= | Silent (SNP) | VAF 46/89 reads (52%) | catalogued as COSV54463155; called by muse, mutect2, varscan2
- KRT38 | c.1104C>T p.N368= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs1350555072, COSV55846173; called by muse, mutect2, varscan2
- MTTP | c.783C>T p.T261= | Silent (SNP) | VAF 46/81 reads (57%) | catalogued as rs539424326; called by muse, mutect2, varscan2
- XIRP2 | c.7344G>T p.V2448= (on ENST00000628543; = p.V2623= on NM_152381.6) | Silent (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2, varscan2
- AC139769.1 | n.214-3817C>A | Intron (SNP) | VAF 28/462 reads (6%) | called by muse, mutect2
- ARL15 | c.*803G>A | 3'UTR (SNP) | VAF 38/62 reads (61%) | called by muse, mutect2, varscan2
- B4GALT1 | c.*2632G>T | 3'UTR (SNP) | VAF 55/112 reads (49%) | called by muse, mutect2, varscan2
- BTG1 | c.*325T>G | 3'UTR (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- CDH6 | c.*981T>A | 3'UTR (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- CRTC3 | c.*522G>A | 3'UTR (SNP) | VAF 34/60 reads (57%) | catalogued as COSV99185761; called by muse, mutect2, varscan2
- DAB2 | c.*624C>A | 3'UTR (SNP) | VAF 67/145 reads (46%) | called by muse, mutect2, varscan2
- DTX1 | c.-190C>T | 5'UTR (SNP) | VAF 63/117 reads (54%) | called by muse, mutect2, varscan2
- ERCC4 | c.*964del | 3'UTR (DEL) | VAF 48/126 reads (38%) | called by mutect2, pindel, varscan2
- FAM241A | c.*1527G>A | 3'UTR (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- FGF5 | c.*2329T>G | 3'UTR (SNP) | VAF 22/34 reads (65%) | called by mutect2, varscan2
- GRIN2A | c.*5676T>C | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2
- HELLPAR | n.200518A>G | RNA (SNP) | VAF 20/54 reads (37%) | catalogued as rs1317256965; called by muse, mutect2, varscan2
- KRT16P2 | n.1051G>A | RNA (SNP) | VAF 110/225 reads (49%) | catalogued as rs536442070; called by muse, mutect2, varscan2
- LINC01098 | n.944C>A | RNA (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2
- MAP1LC3A | c.-32C>T | 5'UTR (SNP) | VAF 7/14 reads (50%) | catalogued as rs1194510427; called by muse, mutect2, varscan2
- MEF2C | chr5:88719995 del GT | 3'Flank (DEL) | VAF 30/68 reads (44%) | called by mutect2, varscan2
- MZT1 | c.*1314T>G | 3'UTR (SNP) | VAF 67/151 reads (44%) | called by muse, mutect2, varscan2
- NR2E1 | c.*1055C>A | 3'UTR (SNP) | VAF 4/35 reads (11%) | called by muse, varscan2
- NTRK2 | c.1397-56631G>T | Intron (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- NUDT12 | c.*575C>A | 3'UTR (SNP) | VAF 25/74 reads (34%) | catalogued as rs1562615618; called by muse, mutect2, varscan2
- PHIP | chr6:79078265 C>G | 5'Flank (SNP) | VAF 11/23 reads (48%) | called by muse, varscan2
- PRRT2 | c.*480C>G | 3'UTR (SNP) | VAF 64/119 reads (54%) | called by muse, mutect2, varscan2
- SASH1 | c.*2696C>G | 3'UTR (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- SOX6 | chr11:15969772 A>T | 3'Flank (SNP) | VAF 46/85 reads (54%) | called by muse, mutect2, varscan2
- THBS2 | c.*1682C>T | 3'UTR (SNP) | VAF 78/158 reads (49%) | catalogued as rs1214574832; called by muse, mutect2, varscan2
- TMTC1 | c.*3988C>T | 3'UTR (SNP) | VAF 53/105 reads (50%) | called by muse, mutect2, varscan2
- TNRC6C | c.*1738A>C | 3'UTR (SNP) | VAF 12/27 reads (44%) | catalogued as rs1267334147; called by muse, mutect2
- TNRC6C | c.*1740A>C | 3'UTR (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2
- TPST2 | c.*157C>T | 3'UTR (SNP) | VAF 53/119 reads (45%) | called by muse, mutect2, varscan2
- Unknown | chr6:22020518 A>C | IGR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- ZSCAN25 | c.*2208T>G | 3'UTR (SNP) | VAF 32/58 reads (55%) | catalogued as rs987441431; called by muse, mutect2, varscan2
